Somatic mutation profile of tumor specimen BA2059D (aliquot aq-BA2059D) from BEATAML1.0 case 2118, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,144 days).
Specimen BA2059D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 470a2337-23ce-4998-a2ff-9c64cf9b31b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2391D (Solid Tissue Normal), aliquot aq-BA2391D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3622f4c3-18f6-4a27-8568-096c667553ef

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC242842.3 | c.1094T>A p.L365Q | Missense Mutation (SNP) | VAF 3/160 reads (2%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1185110962; called by muse, mutect2
- BAZ1A | c.521G>T p.C174F | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as rs922614760, COSV62409827; called by muse, mutect2
- NUP205 | c.4922C>A p.A1641E | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV53665106; called by muse, mutect2
- AJAP1 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.127); called by muse, mutect2
- GCAT | c.152C>A p.T51K | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.22); called by muse, mutect2
- FIGNL1 | c.720G>T p.V240= | Silent (SNP) | VAF 5/93 reads (5%) | called by muse, mutect2
- MEX3B | c.1533G>T p.R511= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
